Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5097, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5097-01A (Primary Tumor).

FINAL DIAGNOSIS

PART 1: RIGHT KIDNEY AND PROXIMAL URETER, RADICAL NEPHRECTOMY –

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, PRESENT IN THE MID RIGHT KIDNEY, 7.0 CM IN MAXIMAL DIMENSION.
- B. PREDOMINANT FUHRMAN NUCLEAR GRADE IS II / IV.
- C. CARCINOMA IS CONFINED BY THE RENAL CAPSULE, WITHOUT EXTRACAPSULAR EXTENSION INTO PERIRENAL OR RENAL SINUS ADIPOSE TISSUE.
- D. OCCLUSIVE TUMOR THROMBUS IS PRESENT IN THE MAIN RENAL VEIN, BUT DOES NOT INVOLVE THE RENAL VEIN MARGIN (SECTIONS 1C-1E).
- E. MICROSCOPIC ANGIOLYMPHATIC INVASION IS PRESENT IN A SMALL PERITUMORAL BLOOD VESSEL (SECTION 1K).
- F. ALL SURGICAL RESECTION MARGINS ARE BENIGN.
- G. BENIGN URETER AND RENAL ARTERY.
- H. NON-NEOPLASTIC KIDNEY AWAY FROM TUMOR WITH MILD ARTERIAL SCLEROSIS, OTHERWISE NO SIGNIFICANT HISTOLOGIC ABNORMALITY (H&E, PAS, METHENAMINE SILVER-TRICHROME, AND TRICHROME STAINS).
- I. ONE (1) BENIGN PERIRENAL LYMPH NODE (0/1) WITH SEVERAL NON-NECROTIZING GRANULOMAS AND FEW SMALL CALCIFICATIONS.
- J. TNM PATHOLOGIC STAGE: T2 N0 (based on two lymph nodes examined) MX (See synoptic).

PART 2: RIGHT ADRENAL GLAND, ARENALECTOMY –

- A. BENIGN ADRENAL GLAND WITH SMALL ADRENAL CORTICAL ADENOMA.
- B. NO EVIDENCE OF MALIGNANCY.

PART 3: INTERAORTOCAVAL LYMPH NODE, EXCISION –

- ONE (1) BENIGN LYMPH NODE (0/1) AND ADIPOSE TISSUE.

Source: NCI Genomic Data Commons file b026cf5e-e83e-49ad-be62-2aaa0d7ea4be (TCGA-B0-5097.35BFE92B-71C8-4375-8FCA-67CD15A17BAF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).